Somatic mutation profile of tumor specimen ALCH-B39Q-TTP1-A (aliquot ALCH-B39Q-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B39Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 79.2 years (28,917 days).
Specimen ALCH-B39Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee784533-5c23-4488-b0e4-a142164ca495.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B39Q-NB1-A (Blood Derived Normal), aliquot ALCH-B39Q-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed52842d-4993-437d-ae34-0404256a8d90

The open-access MAF lists 184 somatic variants for this specimen: 121 protein-altering or splice-affecting, 34 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 34, Intron 16, RNA 5, Splice Site 4, Nonsense Mutation 4, 3'UTR 4, Frame Shift Del 3, Splice Region 2, 5'Flank 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 71/305 reads (23%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- BANP | c.1294C>T p.R432C (on ENST00000286122; = p.R404C on NM_079837.3) | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs765715551; called by muse, mutect2, varscan2
- BAZ2A | c.3598A>G p.M1200V | Missense Mutation (SNP) | VAF 163/511 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1200170118, COSV51638601; called by muse, mutect2, varscan2
- BLOC1S5 | c.472del p.E158Kfs*24 | Frame Shift Del (DEL) | VAF 60/318 reads (19%) | catalogued as COSV55242708; called by pindel, varscan2
- CEPT1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs759078198, COSV64111367; called by muse, mutect2
- COL4A2 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs758260445, COSV64628644; called by muse, mutect2, varscan2
- DCAF8L2 | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.967); catalogued as COSV70548153; called by muse, mutect2, varscan2
- DOCK2 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs752262388, COSV56942620, COSV56968077; called by muse, mutect2, varscan2
- E2F6 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 52/614 reads (8%) | catalogued as COSV56216763; called by muse, mutect2
- ELP1 | c.2806A>G p.I936V | Missense Mutation (SNP) | VAF 91/442 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1239561807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F13A1 | c.1621C>G p.R541G | Missense Mutation (SNP) | VAF 120/593 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV53563222; called by muse, mutect2, varscan2
- IGHV3-33 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 76/529 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as rs1555493727; called by muse, mutect2, varscan2
- KCNH1 | c.2662G>A p.D888N (on ENST00000271751 / NM_172362.3; = p.D861N on NM_002238.4) | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.27); catalogued as rs778733037, COSV99661422; called by muse, mutect2, varscan2
- LRRC7 | c.1323C>T p.S441= (on ENST00000651989 / NM_001370785.2; = p.S408= on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 67/191 reads (35%) | catalogued as rs1471260113; called by muse, mutect2, varscan2
- MGAM2 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV72176171; called by muse, mutect2, varscan2
- MPZ | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 149/352 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.079); catalogued as HM070058; called by muse, varscan2
- MUC16 | c.8032C>G p.L2678V | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs751921182; called by muse, mutect2
- MYLIP | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs754805685; called by muse, mutect2, varscan2
- NRK | c.2406G>C p.K802N | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV54609928; called by muse, mutect2
- OBSCN | c.10847C>T p.S3616L | Missense Mutation (SNP) | VAF 198/425 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs779979102; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5M8 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs956131838; called by muse, mutect2, varscan2
- PHACTR1 | c.1071G>C p.M357I | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100278945; called by muse, mutect2, varscan2
- PPP3CC | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs773037392; called by muse, mutect2, varscan2
- QKI | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 167/517 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1431256473; called by muse, mutect2, varscan2
- RENBP | c.1156C>G p.P386A | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1303313515; called by muse, mutect2, varscan2
- RPIA | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); catalogued as rs962744633, COSV99376391; called by muse, mutect2, varscan2
- SEC14L3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs769756699, COSV53179240; called by muse, mutect2
- SH2D2A | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV63884269; called by muse, mutect2, varscan2
- SHISAL2A | c.97T>C p.C33R | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755301258; called by muse, varscan2
- SLC17A3 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 169/553 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.874); catalogued as COSV57759821; called by muse, mutect2, varscan2
- SLC6A9 | c.2056G>A p.D686N (on ENST00000360584 / NM_201649.4; = p.D632N on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as rs1255122708; called by muse, mutect2, varscan2
- SMG6 | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 125/280 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs372054320; called by muse, mutect2, varscan2
- SNTG2 | c.89C>G p.A30G | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs376992258; called by muse, mutect2, varscan2
- SON | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.925); catalogued as COSV99277169; called by muse, mutect2
- SPATA7 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs267604078, COSV50415827; called by muse, mutect2, varscan2
- SPHKAP | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.34); catalogued as rs199537804; called by muse, mutect2, varscan2
- TOPBP1 | c.3995C>G p.S1332C | Missense Mutation (SNP) | VAF 96/354 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53440040; called by muse, mutect2, varscan2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TRIM51 | c.677del p.L226* | Frame Shift Del (DEL) | VAF 104/964 reads (11%) | catalogued as COSV55264546; called by pindel, varscan2
- TRIM55 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs544219291; called by muse, mutect2, varscan2
- TTN | c.26534C>T p.T8845M (on ENST00000591111; = p.T7918M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/456 reads (38%) | PolyPhen possibly damaging (0.819); catalogued as rs199793620; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- USH1C | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 76/383 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs200428926, COSV50018137; called by muse, mutect2, varscan2
- A2M | c.2744C>A p.T915K | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- AC244197.3 | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 97/614 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTN2 | c.2527-1_2533del p.X843_splice | Splice Site (DEL) | VAF 131/365 reads (36%) | called by mutect2, pindel, varscan2
- ADD2 | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APOBR | c.2232G>T p.E744D (on ENST00000431282; = p.E753D on NM_018690.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- ARAP1 | c.3311A>G p.H1104R (on ENST00000393609 / NM_001040118.2; = p.H859R on NM_015242.4) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ARSL | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 74/427 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASCC1 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 132/806 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ATP2B3 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- BRCA2 | c.912A>T p.E304D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CASD1 | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 135/516 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CD109 | c.4226A>G p.D1409G | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDH4 | c.2424C>A p.H808Q | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CFAP47 | c.8055T>G p.F2685L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP61 | c.3311C>A p.S1104Y | Missense Mutation (SNP) | VAF 139/850 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A6 | c.2804C>G p.S935C | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COL5A1 | c.3143G>A p.G1048E | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CTNND2 | c.2524T>C p.W842R | Missense Mutation (SNP) | VAF 59/546 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CTSF | c.1235A>T p.Y412F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CUX2 | c.63+1G>T p.X21_splice | Splice Site (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- DIDO1 | c.2023A>G p.R675G | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DISP2 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- DNHD1 | c.1328A>T p.E443V | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- DTHD1 | c.1603G>C p.V535L (on ENST00000456874; = p.V370L on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/551 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- EFCAB8 | c.3472G>T p.G1158C | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- EGR3 | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- EIF3A | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EML5 | c.2292G>C p.L764F | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FAM20A | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 50/670 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FREM1 | c.4753del p.D1585Tfs*21 | Frame Shift Del (DEL) | VAF 104/547 reads (19%) | called by mutect2, pindel, varscan2
- GUCY1A2 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- HABP4 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, varscan2
- HIVEP1 | c.5177C>T p.T1726I | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IDS | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFIT1B | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGKV1D-37 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.053); called by mutect2, varscan2
- ILF3 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2
- IZUMO1R | c.29A>G p.E10G | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANSL1L | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 84/518 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- KIF2B | c.1202T>C p.L401P | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KLHL34 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KREMEN2 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- LINGO2 | c.1422G>T p.Q474H | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LRRC7 | c.1322C>A p.S441Y (on ENST00000651989 / NM_001370785.2; = p.S408Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MLKL | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- MORN5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 93/483 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MTA2 | c.1223C>G p.T408S | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MYH13 | c.2399T>A p.L800Q | Missense Mutation (SNP) | VAF 176/373 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- MYH4 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYLK4 | c.850A>T p.T284S | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYOM3 | c.3698A>C p.E1233A | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAGPA | c.955T>C p.S319P | Missense Mutation (SNP) | VAF 17/96 reads (18%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP5 | c.1174C>A p.R392S | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NUP133 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 144/256 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, varscan2
- OR5T1 | c.831C>A p.S277R | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.151); called by muse, mutect2
- OSBPL6 | c.2801G>T p.W934L | Missense Mutation (SNP) | VAF 106/400 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- PCK1 | c.1688C>G p.A563G | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEG3 | c.482-8C>A | Splice Region (SNP) | VAF 51/285 reads (18%) | called by muse, mutect2, varscan2
- PHYHD1 | c.343A>T p.K115* | Nonsense Mutation (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- PNN | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 111/620 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- POGLUT2 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- REV3L | c.5576C>G p.T1859S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SCART1 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLAIN2 | c.1598G>C p.R533T | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SLC25A23 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SLIT2 | c.1059-1G>C p.X353_splice | Splice Site (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- SMARCC2 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 38/740 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPATA31D1 | c.4136G>C p.S1379T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TACR3 | c.910G>C p.V304L | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D25 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TENM1 | c.6097G>T p.G2033C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM132C | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- TRAPPC8 | c.911A>G p.Q304R | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TRIM49C | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 159/900 reads (18%) | called by muse, mutect2, varscan2
- TUBB2B | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBE1 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UHRF1 | c.713G>T p.W238L (on ENST00000612630 / NM_001290050.1; = p.W251L on NM_013282.4) | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UNC79 | c.1979C>T p.P660L (on ENST00000393151 / NM_001346218.2; = p.P483L on NM_020818.5) | Missense Mutation (SNP) | VAF 79/364 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFX | c.2275G>T p.A759S | Missense Mutation (SNP) | VAF 63/478 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACTL6A | c.1260G>T p.G420= | Silent (SNP) | VAF 77/627 reads (12%) | called by muse, mutect2, varscan2
- ADCY2 | c.2439C>T p.F813= | Silent (SNP) | VAF 42/585 reads (7%) | called by muse, mutect2
- AKAP4 | c.2019G>A p.A673= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as rs782658466, COSV62073652; called by muse, mutect2
- CAT | c.750G>A p.A250= | Silent (SNP) | VAF 56/289 reads (19%) | catalogued as rs375051353; called by muse, mutect2, varscan2
- CHAMP1 | c.675C>G p.P225= | Silent (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- CKAP2 | c.1152G>A p.R384= (on ENST00000378037 / NM_001098525.2; = p.R383= on NM_018204.5) | Silent (SNP) | VAF 78/494 reads (16%) | catalogued as rs1457232696; called by muse, mutect2, varscan2
- DCLK1 | c.2092C>A p.R698= (on ENST00000360631 / NM_001330072.2; = p.S722= on NM_004734.5) | Silent (SNP) | VAF 47/217 reads (22%) | catalogued as COSV55201777; called by muse, mutect2, varscan2
- E2F3 | c.132C>T p.F44= | Silent (SNP) | VAF 64/418 reads (15%) | catalogued as rs746277803, COSV60895863, COSV60897568, COSV60900585; called by mutect2, varscan2
- EIF2S3B | c.174C>A p.V58= | Silent (SNP) | VAF 145/453 reads (32%) | called by muse, mutect2, varscan2
- ERBB4 | c.3522G>T p.R1174= | Silent (SNP) | VAF 32/201 reads (16%) | catalogued as COSV100726527; called by muse, mutect2, varscan2
- FOXI3 | c.1131C>T p.G377= | Silent (SNP) | VAF 93/455 reads (20%) | called by muse, mutect2, varscan2
- GGT6 | c.858G>T p.V286= (on ENST00000574154 / NM_001122890.3; = p.V254= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- GUSB | c.750C>T p.V250= | Silent (SNP) | VAF 46/634 reads (7%) | catalogued as rs1410334004; called by muse, mutect2
- HGF | c.1023T>A p.P341= | Silent (SNP) | VAF 92/760 reads (12%) | called by muse, mutect2, varscan2
- LRRC15 | c.1041C>T p.S347= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as rs1272851180; called by muse, mutect2, varscan2
- MAGEE1 | c.645C>A p.A215= | Silent (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- NAALAD2 | c.849T>A p.P283= | Silent (SNP) | VAF 122/641 reads (19%) | called by muse, mutect2, varscan2
- NLRP10 | c.162G>A p.P54= | Silent (SNP) | VAF 69/461 reads (15%) | catalogued as rs767768256; called by muse, mutect2, varscan2
- OR2AG1 | c.459C>A p.S153= | Silent (SNP) | VAF 38/201 reads (19%) | catalogued as COSV100264843, COSV56627057; called by muse, mutect2, varscan2
- OR4C16 | c.339C>A p.L113= | Silent (SNP) | VAF 36/171 reads (21%) | called by muse, mutect2, varscan2
- OR56A1 | c.606A>G p.Q202= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as rs1284623246; called by muse, mutect2, varscan2
- OR56A4 | c.1032C>A p.P344= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV58110097; called by muse, mutect2, varscan2
- OR5H14 | c.807C>T p.D269= | Silent (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- PHKB | c.984T>C p.Y328= | Silent (SNP) | VAF 76/391 reads (19%) | called by muse, mutect2, varscan2
- PIK3C2G | c.4113T>G p.P1371= (on ENST00000676171; = p.P1330= on NM_004570.5) | Silent (SNP) | VAF 98/300 reads (33%) | called by muse, mutect2, varscan2
- PLXNA2 | c.1770G>T p.A590= | Silent (SNP) | VAF 186/374 reads (50%) | called by muse, mutect2, varscan2
- PTCHD4 | c.174C>T p.L58= | Silent (SNP) | VAF 38/211 reads (18%) | called by muse, mutect2, varscan2
- SLC32A1 | c.1548C>T p.I516= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs776847257, COSV54146407; called by muse, mutect2, varscan2
- SLC38A5 | c.555C>G p.L185= | Silent (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- TMEM132C | c.672C>A p.T224= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- TRAM2 | c.663G>A p.Q221= | Silent (SNP) | VAF 82/423 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.67113T>A p.S22371= (on ENST00000591111; = p.S14947= on NM_003319.4) | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as COSV60064382; called by muse, mutect2, varscan2
- WDR35 | c.1455C>T p.T485= (on ENST00000345530 / NM_001006657.2; = p.T474= on NM_020779.4) | Silent (SNP) | VAF 60/316 reads (19%) | called by muse, mutect2, varscan2
- ZNHIT6 | c.1035T>C p.C345= | Silent (SNP) | VAF 30/285 reads (11%) | called by muse, mutect2, varscan2
- AC004947.2 | n.138C>T | RNA (SNP) | VAF 16/192 reads (8%) | catalogued as rs549218139; called by muse, mutect2
- AC093802.1 | n.1914+7082del | Intron (DEL) | VAF 45/264 reads (17%) | called by mutect2, pindel, varscan2
- AL133467.6 | chr14:95668231 G>C | 5'Flank (SNP) | VAF 61/461 reads (13%) | called by muse, mutect2, varscan2
- AVPR2 | c.*231C>A | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- BCLAF3 | c.1951-626C>T | Intron (SNP) | VAF 11/190 reads (6%) | called by muse, mutect2
- CCDC162P | n.1865A>G | RNA (SNP) | VAF 46/277 reads (17%) | catalogued as rs1055044206; called by muse, mutect2, varscan2
- CD99 | c.476-97C>T | Intron (SNP) | VAF 89/629 reads (14%) | catalogued as rs1188150224, COSV66989188; called by muse, mutect2, varscan2
- COL4A5 | c.4977-38A>G | Intron (SNP) | VAF 67/354 reads (19%) | called by muse, mutect2, varscan2
- FAM161A | c.*1074G>T | 3'UTR (SNP) | VAF 144/458 reads (31%) | called by muse, mutect2, varscan2
- FCN1 | c.*306dup | 3'UTR (INS) | VAF 43/204 reads (21%) | called by mutect2, pindel, varscan2
- H2BC15 | c.377+13116G>T | Intron (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- HSD17B10 | c.27+13T>A | Intron (SNP) | VAF 41/390 reads (11%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1708-645C>T | Intron (SNP) | VAF 42/317 reads (13%) | called by muse, mutect2, varscan2
- LINC00482 | n.934G>T | RNA (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- LY6E-DT | n.290A>T | RNA (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- MALRD1 | c.4688-204G>A | Intron (SNP) | VAF 44/166 reads (27%) | catalogued as rs756113099, COSV66005485; called by muse, mutect2, varscan2
- MAP4 | c.1999+3894G>T | Intron (SNP) | VAF 69/237 reads (29%) | called by muse, mutect2, varscan2
- MFRP | chr11:119346130 A>C | 5'Flank (SNP) | VAF 54/287 reads (19%) | called by muse, mutect2, varscan2
- OR7D1P | n.710C>T | RNA (SNP) | VAF 46/249 reads (18%) | catalogued as rs752021542; called by muse, mutect2, varscan2
- OTUD6B | c.316-1757G>C | Intron (SNP) | VAF 91/633 reads (14%) | catalogued as rs905166003; called by muse, mutect2, varscan2
- PABPC1L | c.1660+183A>C | Intron (SNP) | VAF 66/250 reads (26%) | called by muse, mutect2, varscan2
- PDSS1 | c.832-569G>T | Intron (SNP) | VAF 17/345 reads (5%) | called by muse, mutect2
- PRND | chr20:4732478 C>T | 3'Flank (SNP) | VAF 112/592 reads (19%) | catalogued as rs774538033; called by muse, mutect2, varscan2
- PTPRK | c.2841+198T>C | Intron (SNP) | VAF 69/459 reads (15%) | catalogued as COSV63902828; called by muse, mutect2, varscan2
- SHROOM4 | c.*830G>T | 3'UTR (SNP) | VAF 83/572 reads (15%) | called by muse, mutect2, varscan2
- SMAP1 | c.-50A>T | 5'UTR (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- SOX6 | c.445+479C>G | Intron (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2
- TERT | c.1574-47C>T | Intron (SNP) | VAF 38/229 reads (17%) | catalogued as rs780085899; called by muse, mutect2, varscan2
- TMEM201 | c.1765+258C>T | Intron (SNP) | VAF 13/134 reads (10%) | catalogued as rs956960507; called by muse, mutect2, varscan2
